CCDI case PBBUAN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/605e6dc3-ae4f-4513-9efd-f2405f4be91e

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Granulosa cell tumor, juvenile: ICD-O-3 morphology code: 8622/1; Tissue or organ of origin: Ovary; Age at diagnosis: 8.6 years (3,134 days).

Biospecimens (3 samples)
- Sample 0DHZRV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHZS0: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHZS5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
